Somatic mutation profile of tumor specimen MP2PRT-PARUHV-TMP1-A (aliquot MP2PRT-PARUHV-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PARUHV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.8 years (1,403 days).
Specimen MP2PRT-PARUHV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48543651-a0ed-4191-adbe-083a469248fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARUHV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARUHV-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51668af0-cbd2-483c-b2ed-96c4a5eee378

The open-access MAF lists 148 somatic variants for this specimen: 114 protein-altering or splice-affecting, 28 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 28, Nonsense Mutation 12, Intron 3, Splice Region 2, 5'UTR 1, Splice Site 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2M | c.1313C>T p.S438L | Missense Mutation (SNP) | VAF 17/470 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs1390345945; called by muse, mutect2
- ADGRL3 | c.1069C>G p.Q357E (on ENST00000506720 / NM_001322402.2; = p.Q289E on NM_015236.6) | Missense Mutation (SNP) | VAF 18/532 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV101547217, COSV72270438; called by muse, mutect2
- ATP8B3 | c.3623G>A p.R1208Q | Missense Mutation (SNP) | VAF 117/419 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.92); catalogued as rs781549083, COSV100034460; called by muse, mutect2, varscan2
- CADPS | c.3238G>A p.D1080N | Missense Mutation (SNP) | VAF 39/635 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV51884054; called by muse, mutect2
- CCDC33 | c.2003G>A p.R668Q | Missense Mutation (SNP) | VAF 29/366 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374091946; called by muse, mutect2
- CREBBP | c.4278G>A p.T1426= | Splice Region (SNP) | VAF 87/356 reads (24%) | catalogued as rs369225460; called by muse, mutect2, varscan2
- CTCF | c.1702-1G>A p.X568_splice | Splice Site (SNP) | VAF 17/374 reads (5%) | catalogued as COSV50461368; called by muse, mutect2
- CYB5R4 | c.1064A>G p.Y355C | Missense Mutation (SNP) | VAF 59/218 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1562843453; called by muse, mutect2, varscan2
- EOMES | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 139/510 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); catalogued as rs1194716210; called by muse, mutect2, varscan2
- FEZF2 | c.56G>C p.G19A | Missense Mutation (SNP) | VAF 76/956 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.292); catalogued as COSV51863958, COSV51864284; called by muse, mutect2
- GOLGA4 | c.2128C>G p.L710V | Missense Mutation (SNP) | VAF 39/249 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as rs1457679058; called by muse, mutect2, varscan2
- H2AC4 | c.225G>T p.K75N | Missense Mutation (SNP) | VAF 28/595 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV52520182; called by muse, mutect2
- HMCN1 | c.14775G>C p.K4925N | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.076); catalogued as rs1049279757; called by mutect2, varscan2
- HUWE1 | c.11126C>G p.S3709C | Missense Mutation (SNP) | VAF 34/303 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99472622; called by muse, mutect2, varscan2
- ICE2 | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 35/384 reads (9%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.715); catalogued as rs1349298976, COSV99831603; called by muse, mutect2
- IQCH | c.899C>G p.S300C | Missense Mutation (SNP) | VAF 21/441 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.96); catalogued as COSV60051236; called by muse, mutect2
- IRX4 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 234/919 reads (25%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1349287898; called by muse, varscan2
- IZUMO4 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.457); catalogued as COSV61424838, COSV61430627; called by muse, mutect2, varscan2
- LAD1 | c.193G>A p.V65M | Missense Mutation (SNP) | VAF 29/456 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.783); catalogued as rs779029242, COSV66212644; called by muse, mutect2
- LIMCH1 | c.1149C>G p.I383M | Missense Mutation (SNP) | VAF 83/348 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs756277721; called by muse, mutect2, varscan2
- MEN1 | c.1621C>T p.Q541* | Nonsense Mutation (SNP) | VAF 163/516 reads (32%) | catalogued as CM981283, COSV53647073; called by muse, mutect2, varscan2
- NCBP1 | c.1546G>T p.E516* | Nonsense Mutation (SNP) | VAF 16/362 reads (4%) | catalogued as COSV100912555; called by muse, mutect2
- PALLD | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 29/298 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99825887; called by muse, mutect2
- PCCB | c.583C>G p.L195V | Missense Mutation (SNP) | VAF 106/404 reads (26%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.024); catalogued as rs747267484; called by muse, mutect2, varscan2
- PCLO | c.2705C>G p.S902* | Nonsense Mutation (SNP) | VAF 152/546 reads (28%) | catalogued as COSV100438725, COSV61613337; called by muse, mutect2, varscan2
- PIK3C2B | c.2896C>G p.Q966E | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.675); catalogued as COSV65809043; called by muse, mutect2
- PITPNM3 | c.2706C>G p.I902M | Missense Mutation (SNP) | VAF 64/920 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs535998758; called by muse, mutect2
- POFUT2 | c.819G>C p.W273C | Missense Mutation (SNP) | VAF 37/514 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs950601474; called by muse, mutect2
- PROB1 | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 61/1151 reads (5%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs1473913968; called by muse, mutect2
- PYDC1 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 117/504 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs1291557204, COSV57250646, COSV57252095; called by muse, mutect2, varscan2
- RIMS2 | c.1132C>G p.L378V (on ENST00000666250 / NM_001348490.2; = p.L186V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 145/499 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.526); catalogued as COSV99179653; called by muse, mutect2, varscan2
- RO60 | c.961C>G p.P321A | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs930837994, COSV100814495; called by muse, mutect2, varscan2
- SAA1 | c.358G>C p.E120Q | Missense Mutation (SNP) | VAF 56/436 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.127); catalogued as COSV62945914; called by muse, mutect2
- SCYGR5 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 271/923 reads (29%) | catalogued as rs969075869; called by muse, mutect2, varscan2
- SIN3A | c.2254G>C p.E752Q | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV64584034; called by muse, mutect2
- SLC3A1 | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 133/546 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as rs938605477; called by muse, mutect2, varscan2
- SLC6A19 | c.680C>G p.S227C | Missense Mutation (SNP) | VAF 24/482 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99073527; called by muse, mutect2
- SMG9 | c.844C>G p.L282V | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.558); catalogued as COSV54215886; called by muse, mutect2
- SMYD2 | c.10G>C p.E4Q | Missense Mutation (SNP) | VAF 114/432 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.061); catalogued as COSV99055890; called by muse, varscan2
- SRCIN1 | c.2840G>A p.R947Q (on ENST00000621492; = p.R913Q on NM_025248.3) | Missense Mutation (SNP) | VAF 44/539 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs777709629; called by muse, mutect2
- TESMIN | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 110/988 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV99663343; called by muse, mutect2, varscan2
- TLK2 | c.940G>C p.D314H | Missense Mutation (SNP) | VAF 18/416 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100409422; called by muse, mutect2
- TM4SF5 | c.373G>A p.G125S | Missense Mutation (SNP) | VAF 93/388 reads (24%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs894436944; called by muse, mutect2, varscan2
- TUBB4A | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 81/361 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.403); catalogued as COSV51164090, COSV99900116; called by muse, mutect2, varscan2
- USP19 | c.3535C>T p.Q1179* | Nonsense Mutation (SNP) | VAF 34/522 reads (7%) | catalogued as COSV67349541; called by muse, mutect2
- USP8 | c.3190G>C p.D1064H | Missense Mutation (SNP) | VAF 26/410 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as rs1267260385; called by muse, mutect2
- WASHC4 | c.1054C>G p.L352V | Missense Mutation (SNP) | VAF 22/284 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.085); catalogued as rs1347248161; called by muse, mutect2
- ZBTB38 | c.273C>G p.I91M | Missense Mutation (SNP) | VAF 75/262 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58542954; called by muse, mutect2, varscan2
- ZBTB47 | c.1576G>C p.E526Q | Missense Mutation (SNP) | VAF 40/513 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV51765737; called by muse, mutect2
- ZNF182 | c.1375G>C p.E459Q | Missense Mutation (SNP) | VAF 14/375 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV100526993, COSV59357666; called by muse, mutect2
- ACACA | c.5341C>T p.P1781S | Missense Mutation (SNP) | VAF 22/458 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS19 | c.1462C>T p.H488Y | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHCYL2 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 70/982 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- AK9 | c.476C>T p.S159F | Missense Mutation (SNP) | VAF 26/350 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- BAZ1A | c.4477G>C p.E1493Q | Missense Mutation (SNP) | VAF 13/218 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2
- BCHE | c.874C>T p.L292F | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2
- BCR | c.541G>C p.E181Q | Missense Mutation (SNP) | VAF 181/746 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- CACNA1B | c.6192G>C p.Q2064H | Missense Mutation (SNP) | VAF 190/821 reads (23%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- CACNA1H | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 36/898 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.019); called by muse, mutect2
- CACNG1 | c.275C>G p.S92W | Missense Mutation (SNP) | VAF 31/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- CAD | c.3190C>T p.Q1064* | Nonsense Mutation (SNP) | VAF 125/450 reads (28%) | called by muse, mutect2, varscan2
- CCSER1 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 28/466 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CECR2 | c.1066G>C p.E356Q (on ENST00000342247 / NM_001290047.2; = p.E193Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 21/555 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- CFHR5 | c.1203G>C p.M401I | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- CHD2 | c.1223C>G p.S408* | Nonsense Mutation (SNP) | VAF 91/327 reads (28%) | called by muse, mutect2, varscan2
- CHD3 | c.46G>A p.D16N | Missense Mutation (SNP) | VAF 38/580 reads (7%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.001); called by muse, mutect2
- COL18A1 | c.4976C>G p.S1659* (on ENST00000359759 / NM_130444.3; = p.S1424* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 115/671 reads (17%) | called by muse, mutect2, varscan2
- COL4A1 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 26/560 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DCAF1 | c.2765C>G p.S922C | Missense Mutation (SNP) | VAF 175/615 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- DCAF6 | c.1511C>T p.S504L (on ENST00000312263 / NM_001349778.1; = p.S524L on NM_018442.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 89/341 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- DMAC2L | c.593C>T p.S198L | Missense Mutation (SNP) | VAF 51/411 reads (12%) | SIFT tolerated, low confidence (0.95); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAJC18 | c.542G>T p.G181V | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- DOP1A | c.1735C>G p.H579D | Missense Mutation (SNP) | VAF 54/241 reads (22%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- FRMPD1 | c.2689C>G p.L897V | Missense Mutation (SNP) | VAF 23/707 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- GMIP | c.967G>C p.E323Q | Missense Mutation (SNP) | VAF 183/777 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- HDAC9 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 53/290 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- HROB | c.1608G>C p.Q536H | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2
- IGKV1OR2-108 | chr2:113406870 ATTCACAGTG>TCCC | Missense Mutation (DEL) | VAF 36/133 reads (27%) | called by pindel, varscan2*
- INPP1 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 12/360 reads (3%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, mutect2
- KIF24 | c.3470G>C p.R1157T | Missense Mutation (SNP) | VAF 28/704 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.419); called by muse, mutect2
- LY75-CD302 | c.5438C>T p.S1813L | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- LYL1 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 148/652 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- MAP4K2 | c.336G>C p.Q112H | Missense Mutation (SNP) | VAF 42/459 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); called by muse, mutect2
- MGA | c.1377C>G p.F459L | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- NCBP1 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 23/447 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NCKAP5 | c.3691G>C p.E1231Q | Missense Mutation (SNP) | VAF 35/682 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.033); called by muse, mutect2
- NDST2 | c.707C>G p.T236R | Missense Mutation (SNP) | VAF 129/715 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NOTUM | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 34/814 reads (4%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.869); called by muse, mutect2
- NR3C1 | c.1847C>G p.S616* | Nonsense Mutation (SNP) | VAF 14/340 reads (4%) | called by muse, mutect2
- NRG3 | c.1306C>G p.P436A | Missense Mutation (SNP) | VAF 81/442 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR1P1 | c.373G>T p.D125Y | Missense Mutation (SNP) | VAF 29/560 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PABPC5 | c.39G>C p.K13N | Missense Mutation (SNP) | VAF 161/303 reads (53%) | SIFT tolerated, low confidence (0.53); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- PDS5B | c.914C>G p.S305* | Nonsense Mutation (SNP) | VAF 99/399 reads (25%) | called by muse, mutect2, varscan2
- POU4F2 | c.470C>A p.S157* | Nonsense Mutation (SNP) | VAF 46/1192 reads (4%) | called by muse, mutect2
- PRSS35 | c.133C>G p.L45V | Missense Mutation (SNP) | VAF 38/524 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RAB40C | c.705G>A p.M235I | Missense Mutation (SNP) | VAF 162/762 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- RETSAT | c.1490C>G p.S497C | Missense Mutation (SNP) | VAF 24/614 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- SCAND1 | c.299C>G p.S100C | Missense Mutation (SNP) | VAF 42/876 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); called by muse, mutect2
- SELENOI | c.616G>C p.E206Q | Missense Mutation (SNP) | VAF 8/290 reads (3%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLC22A15 | c.839C>A p.S280* | Nonsense Mutation (SNP) | VAF 26/662 reads (4%) | called by muse, mutect2
- STK17B | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 16/309 reads (5%) | called by muse, mutect2
- TBC1D12 | c.370G>C p.D124H | Missense Mutation (SNP) | VAF 36/1192 reads (3%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.339); called by muse, mutect2
- TEX45 | c.556C>G p.R186G | Missense Mutation (SNP) | VAF 20/799 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- THOC7 | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 86/388 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.766); called by muse, varscan2
- TM4SF5 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 107/455 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- TNIP1 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 16/540 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTC8 | c.1171C>A p.Q391K (on ENST00000338104 / NM_001288781.1; = p.Q375K on NM_144596.4) | Missense Mutation (SNP) | VAF 115/530 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- USP9X | c.4907G>C p.R1636T | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- WDR81 | c.3277G>C p.E1093Q (on ENST00000409644 / NM_001163809.2; = p.E42Q on NM_152348.4) | Missense Mutation (SNP) | VAF 55/1002 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.602); called by muse, mutect2
- ZFR | c.1713G>A p.E571= | Splice Region (SNP) | VAF 14/360 reads (4%) | called by muse, mutect2
- ZNF180 | c.1207C>G p.H403D | Missense Mutation (SNP) | VAF 167/569 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF182 | c.1216G>C p.E406Q | Missense Mutation (SNP) | VAF 20/308 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ZNF615 | c.56G>C p.W19S | Missense Mutation (SNP) | VAF 31/414 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2
- ZNF616 | c.934C>G p.L312V | Missense Mutation (SNP) | VAF 88/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- AOC1 | c.501C>G p.L167= | Silent (SNP) | VAF 44/731 reads (6%) | called by muse, mutect2
- AOC2 | c.2097C>T p.F699= (on ENST00000253799 / NM_009590.4; = p.F672= on NM_001158.5) | Silent (SNP) | VAF 38/723 reads (5%) | called by muse, mutect2
- AUP1 | c.906G>A p.Q302= | Silent (SNP) | VAF 20/404 reads (5%) | called by muse, mutect2
- CATSPERG | c.2304C>T p.F768= | Silent (SNP) | VAF 37/621 reads (6%) | catalogued as COSV53048707, COSV99286968; called by muse, mutect2
- CYP26C1 | c.1437C>T p.T479= | Silent (SNP) | VAF 42/1237 reads (3%) | called by muse, mutect2
- DLGAP2 | c.1797C>T p.I599= | Silent (SNP) | VAF 119/493 reads (24%) | catalogued as rs367809240, COSV70097435; called by muse, mutect2, varscan2
- FAM189A1 | c.204C>T p.F68= | Silent (SNP) | VAF 35/591 reads (6%) | catalogued as rs889112158; called by muse, mutect2
- IDNK | c.27G>A p.V9= | Silent (SNP) | VAF 138/561 reads (25%) | called by muse, mutect2, varscan2
- KANK2 | c.1221C>T p.I407= | Silent (SNP) | VAF 12/342 reads (4%) | catalogued as rs1454600805; called by muse, mutect2
- KMT2D | c.2731C>T p.L911= | Silent (SNP) | VAF 36/722 reads (5%) | catalogued as rs751936279; called by muse, mutect2
- MAST3 | c.1491C>G p.L497= | Silent (SNP) | VAF 82/360 reads (23%) | called by muse, mutect2, varscan2
- MMRN2 | c.2022G>A p.P674= | Silent (SNP) | VAF 453/1026 reads (44%) | called by muse, mutect2, varscan2
- NKAIN2 | c.423G>A p.L141= | Silent (SNP) | VAF 47/829 reads (6%) | catalogued as rs753028887; called by muse, mutect2
- NPTX2 | c.843G>C p.L281= | Silent (SNP) | VAF 61/527 reads (12%) | catalogued as COSV55716118; called by muse, mutect2, varscan2
- NXN | c.1290C>G p.L430= | Silent (SNP) | VAF 98/441 reads (22%) | catalogued as rs1166911380; called by muse, mutect2, varscan2
- PDE4A | c.1455C>T p.L485= (on ENST00000380702 / NM_001111307.2; = p.L246= on NM_006202.3) | Silent (SNP) | VAF 42/603 reads (7%) | catalogued as rs1273649498; called by muse, mutect2
- PRL | c.63C>G p.L21= | Silent (SNP) | VAF 130/517 reads (25%) | called by muse, mutect2, varscan2
- RUNX1 | c.909C>T p.F303= (on ENST00000344691 / NM_001001890.3; = p.F330= on NM_001754.5) | Silent (SNP) | VAF 39/983 reads (4%) | catalogued as rs1313529266; called by muse, mutect2
- SERTAD2 | c.673C>T p.L225= | Silent (SNP) | VAF 22/644 reads (3%) | catalogued as rs1270248274; called by muse, mutect2
- SEZ6L2 | c.579C>T p.V193= (on ENST00000308713 / NM_001114099.3; = p.V123= on NM_012410.4) | Silent (SNP) | VAF 40/644 reads (6%) | catalogued as rs1328204325, COSV58097762; called by muse, mutect2
- SIN3A | c.3033C>T p.I1011= | Silent (SNP) | VAF 70/270 reads (26%) | catalogued as rs1253876533, COSV64583681; called by muse, mutect2, varscan2
- SLCO5A1 | c.372C>T p.L124= | Silent (SNP) | VAF 23/696 reads (3%) | catalogued as COSV99480724; called by muse, mutect2
- TCTE3 | c.30G>C p.S10= | Silent (SNP) | VAF 145/590 reads (25%) | called by muse, mutect2, varscan2
- TECTA | c.4182G>C p.L1394= | Silent (SNP) | VAF 56/760 reads (7%) | catalogued as COSV50709930; called by muse, mutect2
- TMEM121B | c.1503C>G p.L501= | Silent (SNP) | VAF 53/912 reads (6%) | catalogued as rs749971144; called by muse, mutect2
- TMEM39B | c.834C>G p.L278= | Silent (SNP) | VAF 16/646 reads (2%) | called by muse, mutect2
- TRIM14 | c.951C>T p.F317= | Silent (SNP) | VAF 111/1043 reads (11%) | catalogued as COSV52965420; called by muse, mutect2, varscan2
- WDFY3 | c.9531C>T p.I3177= | Silent (SNP) | VAF 50/258 reads (19%) | called by muse, mutect2, varscan2
- AC053481.2 | n.1401A>C | RNA (SNP) | VAF 140/596 reads (23%) | called by muse, mutect2
- COPE | c.444-283T>G | Intron (SNP) | VAF 84/629 reads (13%) | called by muse, mutect2, varscan2
- DST | c.4297-1990C>T | Intron (SNP) | VAF 28/370 reads (8%) | catalogued as rs775558662, COSV99759254; called by muse, mutect2
- SLAIN2 | c.1360+10829C>G | Intron (SNP) | VAF 67/343 reads (20%) | called by muse, mutect2, varscan2
- Z99774.2 | chr22:26672571 G>C | 3'Flank (SNP) | VAF 12/446 reads (3%) | called by muse, mutect2
- ZDHHC6 | c.-34C>G | 5'UTR (SNP) | VAF 26/541 reads (5%) | called by muse, mutect2
